CCDI case PBBKPL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/57fb8a59-b560-4dfa-8850-ef51b7fff243

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.1 years (783 days).

Biospecimens (3 samples)
- Sample 0DB9NV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB9NW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DB9NY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
